Gene-level copy-number profile of tumor specimen TCGA-04-1341-01A from TCGA case TCGA-04-1341, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: G3; Age at diagnosis: 85.5 years (31,215 days).
Specimen TCGA-04-1341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.504eb58f-bb8f-4171-b8e2-41f3d6dd8f88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1341-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95a8e70c-0fd0-4660-b5ee-519fd95e45f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,364; copy number 2: 22,975; copy number 3: 20,130; copy number 4: 8,793; copy number 5: 1,431; copy number 6: 977; copy number 7: 225; copy number 8: 3; copy number 9: 230; copy number 10: 192; copy number 11: 5; copy number 12: 66; copy number 13: 326; copy number 14: 1; copy number 15: 47; copy number 17: 43; copy number 20: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1341-01A-01D-0428-01): tumor purity 0.82, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,553 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,129,464–43,996,528, 189 genes, copy number 7–20 (broad region; genes not listed).
- chr1:50,206,084–51,235,096, 20 genes, copy number 13–14: AL592182.1, LINC02808, AL592182.2, AL596275.1, HMGB1P45, FCF1P6, DMRTA2, AL049637.1, FAF1, FAF1-AS1, RNU6-1026P, PHBP12, MRPS6P2, CDKN2C, MIR4421, MIR6500, C1orf185, Y_RNA, CFL1P2, LINC01562.
- chr1:56,854,797–56,996,757, 3 genes, copy number 12 (within-gene range 2–12): C8A, C8B, AL161740.1.
- chr1:75,926,454–76,779,267, 8 genes, copy number 15 (within-gene range 2–15): AC092813.1, AC092813.2, ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567.
- chr8:5,363,371–5,363,650, 1 gene, copy number 6: AC007718.1.
- chr8:5,659,679–6,036,974, 6 genes, copy number 6: AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1.
- chr8:16,598,758–17,910,365, 29 genes, copy number 5: AC011586.2, AC011586.1, RN7SL474P, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2.
- chr11:75,815,210–76,144,232, 1 gene, copy number 15 (within-gene range 4–15): UVRAG.
- chr11:75,911,204–78,582,156, 72 genes, copy number 10–15 (broad region; genes not listed).
- chr11:79,402,022–81,556,425, 14 genes, copy number 6–11: MIR708, MIR5579, AP001978.1, AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr12:66,767–72,186,618, 1,816 genes, copy number 5–13 (broad region; genes not listed).
- chr12:72,249,964–72,276,954, 1 gene, copy number 9: TRHDE-AS1.
- chr14:18,333,726–23,768,998, 406 genes, copy number 9–17 (broad region; genes not listed).
- chr17:21,123,364–22,706,703, 55 genes, copy number 5: DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr19:22,974,883–27,646,483, 51 genes, copy number 6: ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1, AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1, ERVK-28, AC112702.1.
- chr20:9,537,370–9,839,076, 3 genes, copy number 5 (within-gene range 4–5): PAK5, AL353612.2, AL353612.1.
- chr20:13,221,274–31,311,962, 306 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:33,993,646–34,698,790, 26 genes, copy number 6 (within-gene range 4–6): RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1.
- chr21:32,497,967–34,426,017, 59 genes, copy number 5 (within-gene range 4–5): TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2, AP000282.1, LINC01690, OLIG2, LINC00945, OLIG1, AP000289.1, AP000290.1, LINC01548, IFNAR2, AP000295.1, IL10RB-DT, IL10RB, IFNAR1, USF1P1, IFNGR2, TMEM50B, RPS5P3, AP000302.1, DNAJC28, GART, BTF3P6, SON, MIR6501, DONSON, AP000311.1, CRYZL1, ITSN1, ATP5PO, LINC00649, RN7SL740P, AP000569.1, MRPS6, SLC5A3, AP000317.2, RPS5P2, LINC00310, AP000317.1, AP000320.1, KCNE2, SMIM11A, FAM243A, AP000322.2, SMIM34A, AP000322.1.
- chr22:20,299,760–21,081,018, 51 genes, copy number 12: AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4.
- chr22:21,463,963–25,520,854, 285 genes, copy number 5 (broad region; genes not listed).
- chr22:29,073,035–30,932,449, 81 genes, copy number 5–9 (broad region; genes not listed).
- chr22:37,608,725–38,794,198, 70 genes, copy number 5–12 (within-gene range 1–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
